Gene-level copy-number profile of tumor specimen TCGA-DM-A1D8-01A from TCGA case TCGA-DM-A1D8, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 50.1 years (18,311 days).
Specimen TCGA-DM-A1D8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.05e8bb18-c757-433d-b097-711a6f6fa02c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A1D8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae3bf5c9-9a95-42ae-adf3-205c1c5bd603

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 97; copy number 2: 12,026; copy number 3: 31,420; copy number 4: 14,626; copy number 5: 197; copy number 6: 1,454.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A1D8-01A-11D-A151-01): tumor purity 0.75, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 97. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
